Somatic mutation profile of tumor specimen TCGA-GD-A6C6-01A (aliquot TCGA-GD-A6C6-01A-21D-A31L-08) from TCGA case TCGA-GD-A6C6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 64.7 years (23,631 days).
Specimen TCGA-GD-A6C6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06b3a91e-f70e-4fb8-8782-bfc022f296b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GD-A6C6-10A (Blood Derived Normal), aliquot TCGA-GD-A6C6-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e9064fe-971c-4242-9daf-e5c63f2c6218

The open-access MAF lists 311 somatic variants for this specimen: 214 protein-altering or splice-affecting, 89 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 181, Silent 89, Nonsense Mutation 21, Frame Shift Del 4, Intron 4, Frame Shift Ins 3, Splice Site 3, 5'Flank 2, 5'UTR 1, RNA 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.7928-1G>A p.X2643_splice | Splice Site (SNP) | VAF 249/355 reads (70%) | catalogued as rs1555126163, CS080644, COSV53763777; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.7903C>T p.R2635* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as rs794727549, CM114116, COSV56447739; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 49/52 reads (94%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 55/62 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781288, CM993216, COSV52664953, COSV52926626, COSV53155598; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.1504G>A p.G502S | Missense Mutation (SNP) | VAF 155/510 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs150971192, CM1512519; called by muse, mutect2, varscan2
- ABCC4 | c.190T>C p.W64R | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65316629; called by muse, mutect2, varscan2
- ACIN1 | c.3586A>G p.S1196G | Missense Mutation (SNP) | VAF 126/199 reads (63%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.027); catalogued as COSV52980038; called by muse, mutect2, varscan2
- ACSM2B | c.1427C>G p.S476W | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV61658082, COSV61659280; called by muse, mutect2, varscan2
- ACTBL2 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 74/81 reads (91%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.968); catalogued as rs182995342, COSV70661585; called by muse, mutect2, varscan2
- ACTL6B | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV50517290; called by muse, mutect2, varscan2
- ACTR10 | c.1168C>T p.L390F | Missense Mutation (SNP) | VAF 74/139 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV54299533; called by muse, mutect2, varscan2
- ACVR1 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 87/136 reads (64%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV55121528, COSV55122536; called by muse, mutect2, varscan2
- ACVR1 | c.100A>G p.M34V | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs370437421; called by muse, mutect2, varscan2
- ADCY8 | c.1360C>T p.H454Y | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs754714304, COSV53920422; called by muse, mutect2, varscan2
- ADGRL2 | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54680945; called by muse, varscan2
- ADGRL2 | c.263del p.D88Vfs*6 | Frame Shift Del (DEL) | VAF 36/151 reads (24%) | catalogued as COSV54658009, COSV54680988; called by muse*, mutect2, varscan2*
- AGGF1 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV57230627; called by muse, mutect2, varscan2
- AGO3 | c.375C>G p.I125M | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV55795883; called by muse, mutect2, varscan2
- AKNAD1 | c.1966G>C p.D656H | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.741); catalogued as COSV62201909; called by muse, mutect2, varscan2
- ANKIB1 | c.2404G>C p.E802Q | Missense Mutation (SNP) | VAF 319/341 reads (94%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV56064605; called by muse, mutect2, varscan2
- ANKRD49 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV57060531; called by muse, mutect2, varscan2
- ANKZF1 | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 49/82 reads (60%) | catalogued as rs1412806563, COSV99850780; called by muse, mutect2, varscan2
- ARHGAP21 | c.2930G>C p.R977T | Missense Mutation (SNP) | VAF 159/220 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV57609650; called by muse, mutect2, varscan2
- ARHGEF12 | c.4235C>T p.S1412L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV63106561; called by muse, mutect2, varscan2
- ASTN1 | c.1121T>A p.V374E | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.447); catalogued as COSV56079093; called by muse, mutect2, varscan2
- ATP13A3 | c.1654G>T p.E552* | Nonsense Mutation (SNP) | VAF 46/98 reads (47%) | catalogued as COSV99757334; called by muse, mutect2, varscan2
- ATRX | c.6326G>C p.R2109T | Missense Mutation (SNP) | VAF 80/88 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV64877402, COSV64881019; called by muse, mutect2, varscan2
- BAHD1 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 92/103 reads (89%) | catalogued as COSV101346783; called by muse, mutect2, varscan2
- BBS10 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV53887377; called by muse, mutect2, varscan2
- BRWD1 | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV60900698; called by muse, mutect2, varscan2
- BTAF1 | c.4420G>T p.D1474Y | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56437536; called by muse, mutect2, varscan2
- BTBD2 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 7/8 reads (88%) | catalogued as COSV99724905; called by muse, mutect2, varscan2
- CACNA1A | c.2710G>C p.E904Q | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.909); catalogued as COSV64207440; called by muse, mutect2, varscan2
- CAGE1 | c.2084A>G p.H695R (on ENST00000512086; = p.H559R on NM_205864.3) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57080421; called by muse, varscan2
- CARD6 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54568067; called by muse, mutect2, varscan2
- CARHSP1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV60684285; called by muse, mutect2, varscan2
- CASTOR1 | c.32G>C p.R11P | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53165353; called by muse, mutect2, varscan2
- CATSPERG | c.2422G>T p.E808* | Nonsense Mutation (SNP) | VAF 59/135 reads (44%) | catalogued as COSV99286798; called by muse, mutect2, varscan2
- CCAR2 | c.2086G>A p.D696N | Missense Mutation (SNP) | VAF 238/261 reads (91%) | SIFT tolerated (0.19); PolyPhen benign (0.117); catalogued as COSV52385969; called by muse, mutect2, varscan2
- CCDC149 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1369892048, COSV60881011; called by muse, mutect2, varscan2
- CD101 | c.2822C>T p.S941L | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.583); catalogued as COSV56719999; called by muse, mutect2, varscan2
- CEMIP2 | c.3892T>G p.L1298V | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV65488689; called by muse, mutect2, varscan2
- CEP128 | c.3040G>C p.D1014H | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV55385972; called by muse, mutect2, varscan2
- CILP2 | c.8C>G p.S3W | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.585); catalogued as COSV52278658; called by muse, mutect2, varscan2
- CKAP5 | c.4226C>T p.S1409F | Missense Mutation (SNP) | VAF 64/94 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV56372066; called by muse, mutect2, varscan2
- CLIP4 | c.1040C>G p.S347* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as COSV100192251; called by muse, mutect2, varscan2
- CLRN2 | c.609G>T p.L203F | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.856); catalogued as COSV71825253; called by muse, mutect2, varscan2
- CNOT2 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV57505638; called by muse, mutect2, varscan2
- COL5A1 | c.3517A>G p.K1173E | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1014657655, COSV65673083; called by muse, mutect2, varscan2
- COL6A5 | c.6230G>C p.R2077T (on ENST00000312481; = p.R2073T on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55211738; called by muse, mutect2, varscan2
- CRYGB | c.500C>G p.S167C | Missense Mutation (SNP) | VAF 128/217 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53680254, COSV53680810; called by muse, mutect2, varscan2
- CUBN | c.4358G>A p.G1453E | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs761860503, COSV64723387; called by muse, mutect2, varscan2
- CYFIP2 | c.3678G>C p.K1226N (on ENST00000616178 / NM_001291722.2; = p.K1201N on NM_014376.4) | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.932); catalogued as COSV59047001; called by muse, mutect2, varscan2
- DCDC1 | c.619A>T p.N207Y | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV60853341; called by muse, mutect2, varscan2
- DDX54 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.261); catalogued as COSV58375368; called by muse, mutect2, varscan2
- DHTKD1 | c.173G>C p.R58T | Missense Mutation (SNP) | VAF 228/321 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV53805721; called by muse, mutect2, varscan2
- DHX15 | c.1357G>C p.V453L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100391306, COSV61028586; called by muse, mutect2, varscan2
- DHX37 | c.1678G>C p.E560Q | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.601); catalogued as COSV58137657; called by muse, mutect2, varscan2
- DNAH5 | c.7983G>T p.M2661I | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV54243426; called by muse, mutect2, varscan2
- DNAJC6 | c.2041G>T p.D681Y | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54779569; called by muse, mutect2, varscan2
- DPYS | c.368C>A p.P123H | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV60906386, COSV60911578; called by muse, mutect2, varscan2
- DZIP1L | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as rs1178695870, COSV59520079; called by muse, mutect2, varscan2
- EHBP1 | c.2731G>C p.E911Q | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.417); catalogued as COSV50430323, COSV50436890; called by muse, mutect2, varscan2
- EIF5A | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 110/123 reads (89%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as COSV59752279; called by muse, mutect2, varscan2
- ELF3 | c.708G>C p.K236N | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.307); catalogued as COSV62838469, COSV62839686; called by muse, mutect2, varscan2
- ERGIC2 | c.933C>G p.F311L | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1398668966, COSV64112652, COSV64113001; called by muse, mutect2, varscan2
- ESF1 | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV52518687, COSV52523168; called by muse, mutect2, varscan2
- FAM217B | c.918G>A p.W306* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as COSV100674607; called by muse, mutect2, varscan2
- FAP | c.1615C>G p.Q539E | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV51865631; called by muse, mutect2, varscan2
- FARP2 | c.2647G>C p.E883Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV50869622; called by muse, mutect2, varscan2
- FCHO1 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770292906, COSV53184318; called by muse, mutect2, varscan2
- FERMT1 | c.392G>C p.R131T | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54096082; called by muse, mutect2, varscan2
- FGD6 | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 97/371 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); catalogued as COSV59695798, COSV59696453; called by muse, mutect2, varscan2
- FIGNL1 | c.277C>G p.Q93E | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.265); catalogued as COSV63553558, COSV63553910; called by muse, mutect2, varscan2
- FLNB | c.4915G>A p.D1639N | Missense Mutation (SNP) | VAF 86/98 reads (88%) | SIFT tolerated (0.3); PolyPhen benign (0.107); catalogued as COSV55890025; called by muse, mutect2, varscan2
- FLVCR2 | c.83C>G p.S28W | Missense Mutation (SNP) | VAF 132/212 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.648); catalogued as COSV53163886; called by muse, varscan2
- FLVCR2 | c.137C>G p.S46C | Missense Mutation (SNP) | VAF 190/280 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV53163893; called by muse, varscan2
- FOLH1 | c.878C>A p.P293H | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57054225; called by muse, mutect2, varscan2
- GAA | c.2609G>A p.R870Q | Missense Mutation (SNP) | VAF 88/195 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs747076541, COSV56407401; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAPDH | c.441C>G p.I147M | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); catalogued as COSV57521839; called by muse, mutect2, varscan2
- GCM1 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); catalogued as rs1288848414, COSV52523399; called by muse, mutect2, varscan2
- GCM2 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV65276279; called by muse, mutect2, varscan2
- GK | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66734667; called by muse, mutect2, varscan2
- GPD1L | c.990C>G p.I330M | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56991500; called by muse, mutect2, varscan2
- GPR68 | c.265C>A p.H89N | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as rs1363924937, COSV53177119; called by muse, mutect2, varscan2
- GRIK2 | c.2553A>T p.Q851H | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV59758733; called by muse, mutect2, varscan2
- GRM1 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51234199, COSV99268500; called by muse, mutect2, varscan2
- H3-5 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as COSV61187940; called by muse, mutect2, varscan2
- HAUS3 | c.988C>G p.Q330E | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV54723693; called by muse, mutect2, varscan2
- HEY2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64240464; called by muse, mutect2, varscan2
- HPN | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV52885270; called by muse, mutect2, varscan2
- HPRT1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as COSV53778127; called by muse, mutect2, varscan2
- HSPA14 | c.574A>C p.N192H | Missense Mutation (SNP) | VAF 58/227 reads (26%) | SIFT tolerated (0.89); PolyPhen benign (0.018); catalogued as COSV65684872; called by muse, mutect2, varscan2
- HSPG2 | c.2051A>G p.Q684R | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV65975268; called by muse, mutect2, varscan2
- IGF2BP1 | c.209T>C p.I70T | Missense Mutation (SNP) | VAF 52/77 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV51734343; called by muse, mutect2, varscan2
- IGKV2-30 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as rs764823699; called by muse, mutect2, varscan2
- IGSF10 | c.1729C>G p.Q577E | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV56789863; called by muse, mutect2, varscan2
- IL4I1 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763738158, COSV55580240; called by muse, mutect2, varscan2
- ITGA11 | c.1555G>T p.E519* | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as COSV100242012; called by muse, mutect2, varscan2
- KALRN | c.5719G>C p.E1907Q (on ENST00000360013 / NM_001024660.4; = p.E210Q on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/105 reads (87%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.709); catalogued as COSV52262003; called by muse, mutect2, varscan2
- KAT7 | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52016162; called by muse, mutect2
- KCNQ3 | c.2188G>T p.V730F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV66478165; called by muse, mutect2, varscan2
- KIF1B | c.2661C>G p.F887L (on ENST00000377086 / NM_001365952.1; = p.F841L on NM_015074.3) | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.465); catalogued as COSV55813383; called by muse, mutect2, varscan2
- KIF3B | c.1520G>C p.R507T | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.298); catalogued as COSV65228745; called by muse, mutect2, varscan2
- KIF5B | c.2302C>G p.L768V | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV56655040; called by muse, varscan2
- LCLAT1 | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs780540034, COSV58376653; called by muse, mutect2, varscan2
- LIPH | c.179C>G p.S60* | Nonsense Mutation (SNP) | VAF 70/265 reads (26%) | catalogued as CM156807, COSV56183486, COSV99955996; called by muse, mutect2, varscan2
- MAP11 | c.1102C>G p.P368A | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57587712; called by muse, mutect2, varscan2
- MAST4 | c.2887G>C p.D963H (on ENST00000403625 / NM_001164664.2; = p.D774H on NM_015183.3) | Missense Mutation (SNP) | VAF 23/24 reads (96%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.979); catalogued as COSV55135951; called by muse, mutect2, varscan2
- MAST4 | c.3049G>A p.E1017K (on ENST00000403625 / NM_001164664.2; = p.E828K on NM_015183.3) | Missense Mutation (SNP) | VAF 49/50 reads (98%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV55135994; called by muse, mutect2, varscan2
- METTL22 | c.555+1G>A p.X185_splice | Splice Site (SNP) | VAF 69/74 reads (93%) | catalogued as COSV50838389; called by muse, mutect2, varscan2
- METTL3 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52968547, COSV52970549; called by muse, mutect2, varscan2
- METTL3 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 130/196 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52970552; called by muse, mutect2, varscan2
- METTL6 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV67542468; called by muse, mutect2, varscan2
- MIER2 | c.73G>T p.G25W | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV53397523; called by muse, mutect2, varscan2
- MITF | c.780G>C p.L260F (on ENST00000448226 / NM_006722.3; = p.L154F on NM_000248.4) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV58834469; called by muse, mutect2, varscan2
- MKLN1 | c.418G>T p.G140* | Nonsense Mutation (SNP) | VAF 31/84 reads (37%) | catalogued as COSV100759953; called by muse, mutect2, varscan2
- MMACHC | c.719C>G p.S240* | Nonsense Mutation (SNP) | VAF 82/257 reads (32%) | catalogued as COSV99423685; called by muse, mutect2, varscan2
- MST1 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV56535893; called by muse, mutect2, varscan2
- MTUS2 | c.2192A>C p.K731T | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV70918043, COSV70919467, COSV70920728; called by muse, mutect2, varscan2
- MUC16 | c.18089C>G p.S6030* | Nonsense Mutation (SNP) | VAF 87/274 reads (32%) | catalogued as COSV67491151, COSV67507055; called by muse, mutect2, varscan2
- MYH10 | c.3751G>C p.E1251Q | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs1354598775, COSV52607523; called by muse, mutect2, varscan2
- MYH4 | c.2574A>C p.E858D | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV55123560; called by muse, mutect2, varscan2
- MYO1B | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV58435945; called by muse, mutect2, varscan2
- MYORG | c.1324G>T p.D442Y | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV52627535, COSV52628049; called by muse, mutect2, varscan2
- MYT1 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60510960; called by muse, mutect2, varscan2
- NBEAL2 | c.6205G>A p.V2069I | Missense Mutation (SNP) | VAF 49/53 reads (92%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1434709941, COSV52761600; called by muse, mutect2, varscan2
- NDC80 | c.1394T>G p.L465R | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV55249196; called by muse, mutect2, varscan2
- NEIL2 | c.896A>C p.K299T | Missense Mutation (SNP) | VAF 47/51 reads (92%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV52707518; called by muse, mutect2, varscan2
- NFE2L3 | c.890C>G p.S297C | Missense Mutation (SNP) | VAF 55/234 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV50226230, COSV50226506; called by muse, mutect2, varscan2
- NPIPB15 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 69/297 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV70438113; called by muse, mutect2, varscan2
- NPPC | c.363G>C p.M121I | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV54945583; called by muse, mutect2, varscan2
- NRBF2 | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53260073; called by muse, mutect2, varscan2
- OR2F2 | c.557G>T p.R186M | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68833176; called by muse, mutect2, varscan2
- OSTM1 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 49/78 reads (63%) | catalogued as COSV99514260; called by muse, mutect2, varscan2
- P3H3 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs782631453, COSV99301391; called by muse, mutect2
- PACC1 | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 56/179 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV54788858; called by muse, mutect2, varscan2
- PALB2 | c.1827C>G p.I609M | Missense Mutation (SNP) | VAF 58/69 reads (84%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV55168718, COSV55170798; called by muse, mutect2, varscan2
- PDILT | c.675C>G p.F225L | Missense Mutation (SNP) | VAF 84/94 reads (89%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as COSV56703701, COSV56703942; called by muse, mutect2, varscan2
- PDP2 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.52); catalogued as COSV61241316; called by muse, mutect2, varscan2
- PIBF1 | c.1106A>G p.Y369C | Missense Mutation (SNP) | VAF 51/57 reads (89%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV58326782; called by muse, mutect2, varscan2
- PIH1D1 | c.766G>C p.D256H | Missense Mutation (SNP) | VAF 74/167 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as rs1319191343, COSV51808215; called by muse, mutect2, varscan2
- PIK3R3 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs552393862, COSV53110118; called by muse, mutect2, varscan2
- POLK | c.749C>A p.P250Q | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54038185; called by muse, mutect2, varscan2
- POP7 | c.326A>G p.D109G | Missense Mutation (SNP) | VAF 145/151 reads (96%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57450342; called by muse, mutect2, varscan2
- PPP1R21 | c.1228A>G p.T410A | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.967); catalogued as COSV54287460; called by muse, mutect2, varscan2
- PRMT7 | c.791G>C p.S264T | Missense Mutation (SNP) | VAF 79/89 reads (89%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV59832221, COSV59834774; called by muse, mutect2, varscan2
- PTPN9 | c.1684G>C p.E562Q | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1259088932, COSV60725308; called by muse, mutect2, varscan2
- PUM2 | c.2500G>T p.E834* | Nonsense Mutation (SNP) | VAF 40/158 reads (25%) | catalogued as COSV100163611; called by muse, varscan2
- RAB11FIP4 | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV57931632; called by muse, mutect2, varscan2
- RBM26 | c.958G>T p.V320L | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as COSV57398114; called by muse, mutect2, varscan2
- RESF1 | c.1400G>C p.R467T | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV57024548; called by muse, mutect2, varscan2
- RETREG1 | c.857C>A p.S286* (on ENST00000306320 / NM_001034850.2; = p.S145* on NM_019000.4) | Nonsense Mutation (SNP) | VAF 15/28 reads (54%) | catalogued as COSV100104746; called by muse, mutect2, varscan2
- RGP1 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT deleterious (0.05); PolyPhen benign (0.215); catalogued as rs1563972595, COSV65240064; called by muse, mutect2, varscan2
- RHOBTB3 | c.1022C>G p.S341* | Nonsense Mutation (SNP) | VAF 65/157 reads (41%) | catalogued as COSV101183238; called by muse, mutect2, varscan2
- RNF41 | c.789G>C p.E263D | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.171); catalogued as COSV61504857; called by muse, varscan2
- RNPC3 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs774041757, COSV63716489; called by muse, mutect2, varscan2
- SAE1 | c.764G>T p.R255I | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV54297710; called by muse, mutect2, varscan2
- SCRIB | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1384682740, COSV57589784; called by muse, mutect2, varscan2
- SERPINB7 | c.956C>G p.S319* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100320971; called by muse, mutect2, varscan2
- SGPP1 | c.358C>G p.L120V | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs753572707, COSV55976203; called by muse, mutect2, varscan2
- SIK3 | c.2806C>G p.L936V (on ENST00000445177 / NM_001366686.2; = p.L894V on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/209 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.247); catalogued as COSV52620742, COSV52623995; called by muse, mutect2, varscan2
- SIX3 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53228239; called by muse, mutect2, varscan2
- SLC12A7 | c.2793G>C p.Q931H | Missense Mutation (SNP) | VAF 86/145 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV53760869; called by muse, mutect2, varscan2
- SLC35F5 | c.1099G>C p.G367R | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55519796; called by muse, mutect2, varscan2
- SLC4A8 | c.2266C>G p.Q756E | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.403); catalogued as COSV60656725; called by muse, mutect2, varscan2
- SLK | c.2968G>C p.E990Q | Missense Mutation (SNP) | VAF 63/68 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59827919; called by muse, mutect2, varscan2
- SORBS2 | c.2866G>C p.E956Q (on ENST00000284776 / NM_021069.5; = p.E522Q on NM_003603.6) | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV53010310; called by mutect2, varscan2
- SOS2 | c.1853-1G>A p.X618_splice | Splice Site (SNP) | VAF 35/92 reads (38%) | catalogued as COSV53572003; called by muse, mutect2, varscan2
- SPATA31D1 | c.3502A>G p.S1168G | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV61199422; called by muse, mutect2, varscan2
- SPATA46 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 216/242 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751933453, COSV62638501; called by muse, mutect2, varscan2
- SPEN | c.6691G>C p.E2231Q | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV65365925; called by muse, mutect2, varscan2
- STAT4 | c.1990G>C p.D664H | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61831455; called by muse, mutect2, varscan2
- STK38 | c.17C>G p.S6* | Nonsense Mutation (SNP) | VAF 67/249 reads (27%) | catalogued as COSV100007456; called by muse, mutect2, varscan2
- SYNE1 | c.10702G>A p.E3568K (on ENST00000367255 / NM_182961.4; = p.E3575K on NM_033071.3) | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV55059852; called by muse, mutect2, varscan2
- SZT2 | c.3041G>A p.R1014K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV65172766; called by muse, mutect2, varscan2
- TASOR2 | c.5159C>T p.T1720I | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV60168934; called by muse, mutect2, varscan2
- TEX26 | c.841C>G p.H281D | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV66840441; called by muse, mutect2, varscan2
- THADA | c.2989C>T p.P997S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57690121; called by muse, mutect2, varscan2
- THADA | c.2988G>C p.Q996H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57690133; called by muse, mutect2, varscan2
- TIGD2 | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 44/94 reads (47%) | catalogued as COSV100392436; called by muse, mutect2, varscan2
- TMEM135 | c.876C>G p.F292L | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.034); catalogued as COSV59704640; called by muse, mutect2, varscan2
- TNR | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 83/93 reads (89%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs1400966389, COSV54895434; called by muse, mutect2, varscan2
- TP63 | c.842C>G p.T281R | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53216025; called by muse, mutect2
- TRAK2 | c.794G>C p.R265T | Missense Mutation (SNP) | VAF 72/245 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as COSV60274005; called by muse, mutect2, varscan2
- TREM2 | c.159G>C p.Q53H | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.376); catalogued as COSV58295370; called by muse, mutect2, varscan2
- TRHDE | c.774G>C p.E258D | Missense Mutation (SNP) | VAF 79/138 reads (57%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.936); catalogued as COSV53858326; called by muse, mutect2, varscan2
- TRIO | c.3759C>A p.N1253K | Missense Mutation (SNP) | VAF 92/146 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV60086063; called by muse, mutect2, varscan2
- TTC4 | c.606G>C p.Q202H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV100988466, COSV64885044; called by muse, mutect2, varscan2
- TTN | c.82177C>T p.L27393F (on ENST00000591111; = p.L19969F on NM_003319.4) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | PolyPhen possibly damaging (0.587); catalogued as rs374469076, COSV60245251; called by muse, mutect2, varscan2
- TTN | c.80689G>T p.E26897* (on ENST00000591111; = p.E19473* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100623535, COSV60351846; called by muse, mutect2, varscan2
- TTN | c.17726C>G p.P5909R (on ENST00000591111; = p.P4982R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/123 reads (61%) | PolyPhen benign (0.143); catalogued as COSV60245277; called by muse, mutect2, varscan2
- UBA2 | c.1819G>C p.E607Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs773857522, COSV55829680; called by muse, mutect2, varscan2
- UBAC1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 46/54 reads (85%) | SIFT tolerated (0.4); PolyPhen benign (0.257); catalogued as COSV65614464; called by muse, mutect2, varscan2
- UCN3 | c.249C>G p.I83M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV66824219; called by muse, mutect2, varscan2
- VCAN | c.6349G>C p.E2117Q | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV54113034; called by muse, mutect2, varscan2
- WIZ | c.2627G>A p.R876Q (on ENST00000673675 / NM_001371589.1; = p.R139Q on NM_021241.3) | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as rs376481490; called by muse, mutect2, varscan2
- XPNPEP2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 62/64 reads (97%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV64368120; called by muse, mutect2, varscan2
- ZBTB40 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 162/258 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as rs764410116, COSV65146149; called by muse, mutect2, varscan2
- ZC3H7A | c.2231_2236del p.R744_M746delinsL | In Frame Del (DEL) | VAF 57/134 reads (43%) | catalogued as COSV63270914; called by mutect2, pindel, varscan2
- ZFYVE26 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV61330509; called by muse, mutect2, varscan2
- ZMYM5 | c.194C>G p.S65C | Missense Mutation (SNP) | VAF 73/81 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as COSV61989401; called by muse, mutect2, varscan2
- ZNF831 | c.361C>G p.L121V | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100926246, COSV64043567; called by muse, mutect2, varscan2
- ZNF839 | c.491C>G p.S164C (on ENST00000558850 / NM_001267827.1; = p.S280C on NM_018335.5) | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51758940; called by muse, mutect2, varscan2
- ZNHIT2 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.953); catalogued as COSV54204280, COSV54205392, COSV54205400; called by muse, varscan2
- ADGRL2 | c.260_261insT p.D88Rfs*27 | Frame Shift Ins (INS) | VAF 42/158 reads (27%) | called by muse*, mutect2, varscan2*
- DDX52 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- KDM6A | c.524_525dup p.M176Lfs*5 | Frame Shift Ins (INS) | VAF 117/169 reads (69%) | called by mutect2, pindel, varscan2
- MMP28 | c.1388C>A p.P463H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PCNX1 | c.1701dup p.R568Tfs*3 | Frame Shift Ins (INS) | VAF 50/228 reads (22%) | called by mutect2, varscan2
- PTCD2 | c.125del p.G42Efs*12 | Frame Shift Del (DEL) | VAF 43/61 reads (70%) | called by mutect2, pindel, varscan2
- SDHA | c.1980del p.I661Ffs*21 | Frame Shift Del (DEL) | VAF 74/163 reads (45%) | called by mutect2, pindel, varscan2
- STAG2 | c.3130del p.Y1044Tfs*6 | Frame Shift Del (DEL) | VAF 47/70 reads (67%) | called by mutect2, pindel, varscan2
- TRBV2 | c.42G>C p.L14F | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- ABCC4 | c.2580G>A p.V860= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs762094616, COSV65316617; called by muse, mutect2, varscan2
- ACD | c.153C>A p.L51= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV54665585, COSV54667112, COSV54669526; called by muse, mutect2, varscan2
- ADA | c.57C>T p.D19= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs762695968, COSV65740554; called by muse, mutect2, varscan2
- ADRB1 | c.562C>T p.L188= | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as COSV65167967; called by muse, mutect2, varscan2
- AGAP2 | c.2421C>T p.L807= (on ENST00000547588 / NM_001122772.2; = p.L471= on NM_014770.4) | Silent (SNP) | VAF 131/436 reads (30%) | catalogued as COSV57729803, COSV57730629; called by muse, mutect2, varscan2
- AHNAK | c.16419C>G p.G5473= | Silent (SNP) | VAF 56/129 reads (43%) | catalogued as COSV57224782; called by muse, mutect2, varscan2
- AKNA | c.2820T>C p.T940= | Silent (SNP) | VAF 71/188 reads (38%) | catalogued as COSV56314234; called by muse, mutect2, varscan2
- AMMECR1L | c.30C>G p.L10= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs201713365, COSV55761533; called by muse, mutect2, varscan2
- ASAP3 | c.486G>A p.E162= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV60877065; called by muse, mutect2, varscan2
- BRD2 | c.1197C>G p.V399= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV66374248; called by muse, mutect2, varscan2
- BRD4 | c.609G>A p.S203= | Silent (SNP) | VAF 163/461 reads (35%) | catalogued as rs1326449194, COSV54591781; called by muse, mutect2, varscan2
- C5AR1 | c.228C>T p.L76= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as COSV61893075; called by muse, mutect2, varscan2
- CCR5 | c.312G>A p.L104= | Silent (SNP) | VAF 158/172 reads (92%) | catalogued as COSV52750965, COSV52752548; called by muse, mutect2, varscan2
- CDT1 | c.60C>T p.I20= | Silent (SNP) | VAF 14/16 reads (88%) | catalogued as rs1250753922, COSV56347303, COSV56348860; called by muse, mutect2
- CPAMD8 | c.1467C>T p.L489= (on ENST00000651564; = p.L442= on NM_015692.5) | Silent (SNP) | VAF 65/106 reads (61%) | catalogued as COSV52237995; called by muse, mutect2, varscan2
- CPM | c.18C>T p.L6= | Silent (SNP) | VAF 35/129 reads (27%) | catalogued as COSV58034961; called by muse, mutect2, varscan2
- CUBN | c.10164C>T p.F3388= | Silent (SNP) | VAF 5/87 reads (6%) | catalogued as COSV100912648; called by muse, mutect2
- CUBN | c.9225G>A p.V3075= | Silent (SNP) | VAF 28/167 reads (17%) | catalogued as COSV64723383; called by muse, mutect2, varscan2
- CUBN | c.3864T>C p.Y1288= | Silent (SNP) | VAF 40/188 reads (21%) | catalogued as COSV64723392; called by muse, mutect2, varscan2
- DCHS1 | c.8769C>G p.T2923= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100197645; called by muse, varscan2
- DECR1 | c.984C>G p.L328= | Silent (SNP) | VAF 48/113 reads (42%) | catalogued as COSV55169917, COSV99616651; called by muse, mutect2, varscan2
- DENND5B | c.2049G>A p.R683= | Silent (SNP) | VAF 61/274 reads (22%) | catalogued as COSV60906346; called by muse, mutect2, varscan2
- DHTKD1 | c.1509G>A p.L503= | Silent (SNP) | VAF 112/220 reads (51%) | catalogued as COSV53805734; called by muse, mutect2, varscan2
- DHX37 | c.1800G>A p.E600= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV58137643; called by muse, mutect2
- DXO | c.861G>A p.P287= | Silent (SNP) | VAF 38/135 reads (28%) | catalogued as rs374204728, COSV61714669; called by muse, mutect2, varscan2
- E2F1 | c.489G>A p.Q163= | Silent (SNP) | VAF 125/228 reads (55%) | catalogued as COSV58535882; called by muse, mutect2, varscan2
- EFCAB11 | c.270A>G p.Q90= | Silent (SNP) | VAF 66/91 reads (73%) | catalogued as COSV50861676; called by muse, mutect2, varscan2
- EPHA3 | c.516T>A p.G172= | Silent (SNP) | VAF 41/193 reads (21%) | catalogued as COSV60719699; called by muse, mutect2, varscan2
- FAM222A | c.987C>T p.L329= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV62723828; called by muse, mutect2, varscan2
- FAM81B | c.585T>C p.T195= | Silent (SNP) | VAF 52/61 reads (85%) | catalogued as COSV51985763; called by muse, mutect2, varscan2
- FANCM | c.2310C>T p.H770= | Silent (SNP) | VAF 26/136 reads (19%) | catalogued as rs566935444, COSV57504637; called by muse, mutect2, varscan2
- FER1L6 | c.2670G>A p.E890= | Silent (SNP) | VAF 103/344 reads (30%) | catalogued as COSV67551979; called by muse, mutect2, varscan2
- FMNL1 | c.1032C>T p.V344= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV58958377; called by muse, mutect2, varscan2
- GPR182 | c.1086C>T p.I362= | Silent (SNP) | VAF 55/197 reads (28%) | catalogued as COSV55626855; called by muse, mutect2, varscan2
- GRHL3 | c.1590C>G p.L530= (on ENST00000350501 / NM_198174.3; = p.L535= on NM_021180.3) | Silent (SNP) | VAF 55/207 reads (27%) | catalogued as COSV52569764; called by muse, mutect2, varscan2
- GSTM3 | c.436C>T p.L146= | Silent (SNP) | VAF 82/293 reads (28%) | catalogued as COSV56662837; called by muse, mutect2, varscan2
- HIVEP2 | c.2301T>G p.P767= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV50037035; called by muse, mutect2, varscan2
- HOOK3 | c.1579T>C p.L527= | Silent (SNP) | VAF 63/67 reads (94%) | catalogued as rs750104642, COSV56886017; called by muse, mutect2, varscan2
- IFNGR1 | c.1335C>T p.L445= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as COSV62992498; called by muse, mutect2, varscan2
- ITIH6 | c.2841C>T p.L947= | Silent (SNP) | VAF 44/44 reads (100%) | catalogued as COSV54492605, COSV54493416; called by muse, mutect2, varscan2
- ITPR3 | c.5934C>T p.I1978= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV65413289; called by muse, mutect2, varscan2
- KCNJ16 | c.12C>T p.Y4= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs377652819; called by muse, mutect2, varscan2
- KCNJ6 | c.621C>T p.T207= | Silent (SNP) | VAF 62/68 reads (91%) | catalogued as COSV55719825; called by muse, mutect2, varscan2
- KLK12 | c.24C>A p.L8= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV51578390; called by muse, mutect2, varscan2
- KNTC1 | c.6069G>A p.Q2023= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV61082808, COSV61085388; called by muse, mutect2, varscan2
- MAP3K7CL | c.285C>T p.V95= | Silent (SNP) | VAF 71/80 reads (89%) | catalogued as COSV54511497; called by muse, mutect2, varscan2
- MPND | c.1215C>T p.F405= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV53659004; called by muse, mutect2, varscan2
- MUC6 | c.4077G>A p.T1359= | Silent (SNP) | VAF 120/134 reads (90%) | catalogued as rs757135128, COSV70146950; called by muse, mutect2, varscan2
- MYBBP1A | c.2148G>A p.L716= | Silent (SNP) | VAF 97/108 reads (90%) | catalogued as COSV54601558; called by muse, mutect2, varscan2
- NDUFAB1 | c.312T>C p.F104= | Silent (SNP) | VAF 20/84 reads (24%) | called by muse, varscan2
- NPPA | c.120C>T p.F40= | Silent (SNP) | VAF 127/203 reads (63%) | catalogued as COSV56742254; called by muse, mutect2, varscan2
- NR3C2 | c.1641G>C p.L547= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as COSV60997101; called by muse, mutect2, varscan2
- NUDT16 | c.186G>A p.V62= | Silent (SNP) | VAF 116/129 reads (90%) | catalogued as rs774219967, COSV63248748; called by muse, mutect2, varscan2
- NUP58 | c.1761G>A p.L587= | Silent (SNP) | VAF 51/86 reads (59%) | catalogued as COSV67751887; called by muse, mutect2, varscan2
- OR52I1 | c.747G>A p.V249= | Silent (SNP) | VAF 94/109 reads (86%) | catalogued as COSV56169475; called by muse, mutect2, varscan2
- OR6N1 | c.555G>A p.L185= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as COSV58649812; called by muse, mutect2, varscan2
- OR8H3 | c.705G>A p.Q235= | Silent (SNP) | VAF 37/136 reads (27%) | catalogued as COSV100538744, COSV57907222, COSV57907840; called by muse, mutect2, varscan2
- ORC4 | c.120G>T p.V40= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as COSV51576084; called by muse, mutect2, varscan2
- PCDH15 | c.891C>T p.P297= | Silent (SNP) | VAF 133/147 reads (90%) | catalogued as COSV57365995; called by muse, mutect2, varscan2
- PCDHA8 | c.135G>A p.V45= | Silent (SNP) | VAF 58/141 reads (41%) | catalogued as COSV65339367, COSV65340630; called by muse, varscan2
- PIWIL4 | c.2241A>T p.V747= | Silent (SNP) | VAF 39/79 reads (49%) | catalogued as COSV54411370; called by muse, mutect2, varscan2
- PLEC | c.12033C>G p.L4011= (on ENST00000322810 / NM_201380.4; = p.L3901= on NM_000445.5) | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV59675256; called by muse, mutect2, varscan2
- PLEKHA7 | c.2337G>C p.L779= | Silent (SNP) | VAF 70/177 reads (40%) | catalogued as COSV63049434; called by muse, mutect2, varscan2
- PLXNA1 | c.5295G>A p.K1765= | Silent (SNP) | VAF 140/157 reads (89%) | catalogued as COSV52530855; called by muse, mutect2, varscan2
- PLXNA4 | c.2460C>T p.D820= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV58150568; called by muse, mutect2, varscan2
- POLR1A | c.5106C>T p.V1702= | Silent (SNP) | VAF 137/218 reads (63%) | catalogued as rs750185043, COSV55693129; called by muse, mutect2, varscan2
- QTRT1 | c.753G>A p.P251= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as rs146967568; called by muse, mutect2, varscan2
- RECQL4 | c.1737G>A p.L579= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as COSV99468036; called by muse, mutect2, varscan2
- SECISBP2L | c.2505G>A p.K835= (on ENST00000559471 / NM_001193489.2; = p.K790= on NM_014701.4) | Silent (SNP) | VAF 110/198 reads (56%) | catalogued as COSV55936666; called by muse, mutect2, varscan2
- SMARCC1 | c.2472G>A p.V824= | Silent (SNP) | VAF 37/47 reads (79%) | catalogued as COSV54383489; called by muse, mutect2, varscan2
- SPEF2 | c.3039C>A p.V1013= | Silent (SNP) | VAF 94/178 reads (53%) | catalogued as COSV61551936; called by muse, varscan2
- SREBF2 | c.486G>A p.T162= | Silent (SNP) | VAF 61/121 reads (50%) | catalogued as rs373113186; called by muse, mutect2, varscan2
- TAF3 | c.1380C>T p.S460= | Silent (SNP) | VAF 33/215 reads (15%) | catalogued as rs756303593, COSV60209881; called by muse, mutect2, varscan2
- TBCD | c.985C>T p.L329= | Silent (SNP) | VAF 52/109 reads (48%) | catalogued as COSV62801905, COSV62805683; called by muse, mutect2, varscan2
- TLR2 | c.2010C>T p.F670= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV52607601; called by muse, mutect2, varscan2
- TPBG | c.486C>T p.F162= | Silent (SNP) | VAF 174/271 reads (64%) | catalogued as rs1029732607, COSV63882948; called by muse, mutect2, varscan2
- TRHR | c.381C>T p.I127= | Silent (SNP) | VAF 57/129 reads (44%) | catalogued as COSV61234002; called by muse, mutect2, varscan2
- TRPS1 | c.2245C>T p.L749= (on ENST00000220888 / NM_001330599.2; = p.L762= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 205/308 reads (67%) | catalogued as COSV55254696, COSV55255265; called by muse, mutect2, varscan2
- TTN | c.25152C>T p.H8384= (on ENST00000591111; = p.H7457= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 101/364 reads (28%) | catalogued as rs908525686, COSV60245267; called by muse, mutect2, varscan2
- UBN1 | c.2454G>A p.T818= | Silent (SNP) | VAF 51/127 reads (40%) | catalogued as rs1458992854, COSV52167269; called by muse, mutect2, varscan2
- USP16 | c.2223C>G p.L741= | Silent (SNP) | VAF 105/117 reads (90%) | catalogued as COSV54505501; called by muse, mutect2, varscan2
- VWA3B | c.1761G>A p.L587= | Silent (SNP) | VAF 31/122 reads (25%) | catalogued as COSV68245465; called by muse, mutect2, varscan2
- XRCC5 | c.426C>T p.F142= | Silent (SNP) | VAF 34/56 reads (61%) | catalogued as rs376163776; called by muse, mutect2, varscan2
- ZNF154 | c.1230G>A p.E410= | Silent (SNP) | VAF 40/78 reads (51%) | catalogued as rs928749291, COSV70745357; called by muse, mutect2, varscan2
- ZNF250 | c.93C>G p.L31= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as rs1416290039, COSV52970251; called by muse, mutect2, varscan2
- ZNF407 | c.3234C>G p.L1078= | Silent (SNP) | VAF 19/22 reads (86%) | catalogued as COSV55264210; called by muse, mutect2, varscan2
- ZNF785 | c.984C>G p.L328= | Silent (SNP) | VAF 40/76 reads (53%) | catalogued as COSV67876512; called by muse, mutect2, varscan2
- ZNHIT2 | c.963G>C p.R321= | Silent (SNP) | VAF 33/154 reads (21%) | catalogued as COSV54205390; called by muse, varscan2
- ZSWIM3 | c.105C>T p.S35= | Silent (SNP) | VAF 70/231 reads (30%) | catalogued as rs766903860, COSV54170650; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822732 G>A | 5'Flank (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- AL662899.2 | c.367+264G>A | Intron (SNP) | VAF 45/149 reads (30%) | catalogued as COSV65508116; called by muse, mutect2, varscan2
- DDHD1 | chr14:53152794 T>C | 5'Flank (SNP) | VAF 18/42 reads (43%) | catalogued as rs1414767127, COSV60361422; called by muse, mutect2, varscan2
- DNA2 | c.-48C>A | 5'UTR (SNP) | VAF 72/82 reads (88%) | catalogued as COSV64429652; called by muse, mutect2, varscan2
- NLRP7 | c.2810+2771C>G | Intron (SNP) | VAF 47/125 reads (38%) | catalogued as COSV60179279; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1495G>A | RNA (SNP) | VAF 32/98 reads (33%) | catalogued as rs553828642; called by muse, mutect2, varscan2
- SLC6A15 | c.756+58C>G | Intron (SNP) | VAF 30/100 reads (30%) | catalogued as rs1210138005, COSV57027413; called by muse, mutect2, varscan2
- SYTL2 | c.1459+1722G>T | Intron (SNP) | VAF 38/131 reads (29%) | catalogued as COSV60361931; called by muse, mutect2, varscan2
